TCGA case TCGA-AA-3516 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d9d7f0d4-fa64-48f2-8037-52cbf0b34ad8

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 74 years; Vital status: Dead; Days to death: 396 days (1.1 years).

Diagnoses (4)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 74.8 years (27,303 days); Year of diagnosis: 2007; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Days to last follow up: 396 days (1.1 years).
   Pathology details: Lymph nodes positive: 7; Lymph nodes tested: 26; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the rectum (histology not recorded by GDC). AJCC pathologic M: M0.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial Agent.
   Treatment given: Treatment type: Radiation Therapy, NOS.
3. Prior malignancy of the skin (histology not recorded by GDC). AJCC pathologic M: M1.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Prior malignancy (histology not recorded by GDC). AJCC pathologic M: M1.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 396.

Molecular and laboratory tests
- CEA: 1.41 ng/mL.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3516-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.6; Shortest dimension: 0.3.
  Slide TCGA-AA-3516-01A-01-BS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-AA-3516-01A-02-BS2: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-AA-3516-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-3516-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-AA-3516-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.9; Shortest dimension: 0.6.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 1.41; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Skin; Other malignancy histological type: Secondary malignant neoplasm of other sites: secondary neoplasm of skin.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Rectum; Other malignancy histological type: Malignant Neoplasm of rectum.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -5479.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy anatomic site: no specification of site; Other malignancy histological type: Malignant neoplasm without specification of site.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy skin cancer. No systemic chemotherapy or radiation. Prior malignancy rectal cancer treated w/ systemic chemotherapy.
- Prior malignancy: Prior malignancy skin cancer. No systemic chemotherapy or radiation. Prior malignancy rectal cancer treated w/ systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 396 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 396 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 396 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AA-3516-01): tumor purity 0.39, ploidy 1.99, whole-genome doublings 0 (call status: legacy_call).
